Gene-level copy-number profile of tumor specimen ALCH-B4FZ-TTP1-A from ALCHEMIST case ALCH-B4FZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.3 years (26,043 days).
Specimen ALCH-B4FZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 796638dd-c213-486d-b6c4-87f07cd714a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4FZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,261 have no estimate.
https://portal.gdc.cancer.gov/files/61cf07ef-30e5-45df-8cbf-e787b3f8eb45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 201; copy number 1: 2,830; copy number 2: 47,952; copy number 3: 6,991; copy number 4: 290; copy number 5: 58; copy number 6: 11; copy number 7: 6; copy number 8: 5; copy number 9: 1; copy number 10: 2; copy number 12: 6; copy number 13: 1; copy number 14: 1; copy number 15: 1; copy number 16: 1; copy number 18: 1; copy number 25: 4.

Homozygous deletions (total copy number 0; autosomes only): 195 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,922,554–12,928,253, 2 genes (within-gene range 0–2): RNU6-1072P, PRAMEF29P.
- chr1:93,934,479–93,935,244, 1 gene: AL117351.1.
- chr1:111,909,336–111,998,842, 2 genes (within-gene range 0–1): KCND3-AS1, LINC01750.
- chr1:112,820,170–112,890,922, 3 genes: LINC01356, LINC01357, AL390729.1.
- chr1:114,089,291–114,153,880, 1 gene: SYT6.
- chr1:115,641,970–115,698,224, 1 gene: VANGL1.
- chr1:161,671,978–161,674,824, 1 gene (within-gene range 0–4): AL451067.1.
- chr2:44,927,914–44,939,028, 5 genes (within-gene range 0–1): AC012354.9, AC012354.7, AC012354.8, AC012354.4, AC012354.3.
- chr2:89,170,775–89,310,144, 18 genes (within-gene range 0–1): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr2:89,913,982–91,714,745, 40 genes (within-gene range 0–1): IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2.
- chr3:75,415,070–75,538,029, 4 genes (within-gene range 0–2): ALG1L6P, FAM86DP, LINC02018, ENPP7P2.
- chr4:49,486,926–49,524,185, 5 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr6:106,969,831–107,051,586, 2 genes: CD24, MTRES1.
- chr9:21,201,469–21,240,005, 7 genes: IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14.
- chr10:38,713,195–38,719,229, 1 gene: CHEK2P5.
- chr10:42,149,310–42,149,549, 1 gene: KSR1P1.
- chr10:103,479,603–103,517,393, 1 gene (within-gene range 0–1): NEURL1-AS1.
- chr11:1,662,584–1,663,343, 1 gene: AP006285.1.
- chr11:71,473,503–71,473,568, 1 gene (within-gene range 0–1): MIR6754.
- chr12:132,200,436–132,201,287, 1 gene (within-gene range 0–3): AC138466.4.
- chr13:112,056,845–112,108,015, 2 genes (within-gene range 0–1): SOX1-OT, SOX1.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:18,588,274–18,588,315, 1 gene (within-gene range 0–1): CR383656.9.
- chr15:22,773,063–22,829,789, 1 gene (within-gene range 0–2): NIPA1.
- chr15:100,126,106–100,129,743, 1 gene (within-gene range 0–2): AC022710.1.
- chr16:898,967–905,224, 1 gene (within-gene range 0–4): AL008727.1.
- chr16:89,818,179–89,871,319, 1 gene: SPIRE2.
- chr16:89,906,157–89,920,973, 2 genes (within-gene range 0–2): AC092143.3, MC1R.
- chr16:90,039,761–90,047,773, 1 gene (within-gene range 0–1): URAHP.
- chr17:31,518,432–31,518,729, 1 gene (within-gene range 0–2): RN7SL45P.
- chr18:37,273,706–37,306,333, 2 genes (within-gene range 0–1): AC090386.1, AC090386.2.
- chr19:2,002,580–2,003,581, 1 gene (within-gene range 0–2): AC004678.2.
- chr19:24,146,701–24,163,425, 2 genes: AC073534.2, AC073534.1.
- chr20:31,475,288–31,487,574, 2 genes (within-gene range 0–2): REM1, LINC00028.
- chr20:51,902,291–51,905,030, 2 genes: RNU6-347P, RNU7-6P.
- chr21:8,680,538–13,120,807, 47 genes: CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:17,178,790–17,258,235, 3 genes (within-gene range 0–1): ADA2, AC005300.1, FAM32BP.
- chr22:18,400,407–18,500,594, 3 genes: PPP1R26P3, FAM230A, AC023490.2.
- chr22:18,623,339–18,719,341, 4 genes: SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:18,833,694–18,861,049, 3 genes (within-gene range 0–1): E2F6P1, AC008132.1, BCRP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 93 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,137,017–1,144,056, 1 gene, copy number 8: LINC01342.
- chr1:1,249,777–1,251,334, 1 gene, copy number 5: AL162741.1.
- chr1:2,581,560–2,584,533, 1 gene, copy number 5: AL139246.3.
- chr1:2,590,639–2,633,016, 1 gene, copy number 5 (within-gene range 2–5): MMEL1.
- chr2:232,520,388–232,525,716, 1 gene, copy number 16: PRSS56.
- chr2:242,088,633–242,160,153, 3 genes, copy number 5: LINC01881, CICP10, SEPTIN14P2.
- chr4:1,027,678–1,028,972, 1 gene, copy number 14: AC019103.1.
- chr7:70,972–95,683, 2 genes, copy number 5 (within-gene range 2–5): AC093627.1, AC093627.6.
- chr7:36,781,008–36,819,690, 2 genes, copy number 5: AC007349.3, NPM1P18.
- chr9:61,581,813–61,662,690, 4 genes, copy number 12: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr10:132,433,733–132,441,484, 1 gene, copy number 5: AL451069.3.
- chr10:132,508,394–132,518,367, 1 gene, copy number 5: AL451069.1.
- chr11:1,665,597–1,667,856, 1 gene, copy number 8: FAM99A.
- chr11:2,268,495–2,270,952, 1 gene, copy number 6: ASCL2.
- chr11:2,376,177–2,403,878, 2 genes, copy number 5 (within-gene range 2–5): CD81, TSSC4.
- chr12:132,186,735–132,190,997, 2 genes, copy number 5: LINC02361, AC138466.1.
- chr14:105,526,583–105,530,202, 1 gene, copy number 10: TMEM121.
- chr14:105,583,731–105,588,395, 1 gene, copy number 13: IGHA2.
- chr15:22,664,359–22,686,213, 1 gene, copy number 5: WHAMMP3.
- chr16:975,761–986,979, 2 genes, copy number 5 (within-gene range 4–5): CEROX1, SOX8.
- chr16:1,678,256–1,702,280, 2 genes, copy number 5 (within-gene range 4–5): JPT2, AL031009.1.
- chr16:1,770,286–1,773,150, 2 genes, copy number 12 (within-gene range 4–12): NME3, MRPS34.
- chr16:1,790,413–1,794,971, 1 gene, copy number 8 (within-gene range 4–8): IGFALS.
- chr16:1,826,941–1,884,294, 4 genes, copy number 5 (within-gene range 1–5): FAHD1, MEIOB, AL031722.1, LINC00254.
- chr16:2,090,195–2,090,284, 1 gene, copy number 5 (within-gene range 5–6): MIR1225.
- chr16:2,106,669–2,133,204, 5 genes, copy number 5 (within-gene range 5–11): MIR6511B1, AC009065.6, AC009065.3, Y_RNA, MIR4516.
- chr16:2,140,803–2,196,605, 6 genes, copy number 5–8: RAB26, SNHG19, SNORD60, AC009065.9, TRAF7, CASKIN1.
- chr16:2,339,150–2,458,854, 4 genes, copy number 5 (within-gene range 2–5): ABCA17P, CCNF, AC106820.6, MIR6767.
- chr16:2,537,979–2,603,188, 8 genes, copy number 5 (within-gene range 4–5): PDPK1, AC093525.6, AC093525.5, AC093525.7, AC093525.4, AC093525.3, AC093525.9, AC093525.10.
- chr16:2,644,084–2,645,214, 1 gene, copy number 18: AC141586.2.
- chr16:88,803,789–88,809,258, 1 gene, copy number 5: CDT1.
- chr19:1,103,926–1,174,268, 2 genes, copy number 5–7: GPX4, SBNO2.
- chr19:1,238,179–1,239,522, 1 gene, copy number 9: AC004221.1.
- chr19:1,248,553–1,279,244, 4 genes, copy number 6: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,753,506–1,780,988, 1 gene, copy number 5: ONECUT3.
- chr20:62,841,005–62,861,822, 1 gene, copy number 8 (within-gene range 3–8): TCFL5.
- chr20:63,540,810–63,556,695, 3 genes, copy number 6: SRMS, AL121829.2, FNDC11.
- chr22:18,361,820–18,391,105, 2 genes, copy number 7: FAM230J, AC011718.1.
- chr22:18,501,794–18,524,935, 3 genes, copy number 7: FAM247B, GGTLC3, Metazoa_SRP.
- chr22:18,533,646–18,611,919, 4 genes, copy number 25: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.

Autosomal genes at a single copy (total copy number 1): 2,799. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
